Somatic mutation profile of tumor specimen TCGA-WB-A818-01A (aliquot TCGA-WB-A818-01A-11D-A35I-08) from TCGA case TCGA-WB-A818, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 37.2 years (13,596 days).
Specimen TCGA-WB-A818-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d97a9375-ae44-465f-89a2-7363bded0a94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A818-10A (Blood Derived Normal), aliquot TCGA-WB-A818-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e96ed489-7e02-4f12-b518-437a0d8741c4

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMKN | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as rs746196142, COSV60088708; called by muse, mutect2
- MEFV | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422054832; called by muse, mutect2, varscan2
- NF1 | c.6927_6928del p.P2310Sfs*16 (on ENST00000358273 / NM_001042492.3; = p.P2289Sfs*16 on NM_000267.3) | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | called by mutect2, pindel, varscan2
- PPP6C | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2
- SORBS1 | c.1741C>T p.P581S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.433); called by muse, mutect2, varscan2
